Gene-level copy-number profile of tumor specimen TCGA-13-1410-01A from TCGA case TCGA-13-1410, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: GX; Age at diagnosis: 57.4 years (20,950 days).
Specimen TCGA-13-1410-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e52a7802-fd03-4d83-b0ec-b06cd7a1aedc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1410-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/01892891-8ddc-4c1a-8afa-f136f407434b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 176; copy number 2: 14,571; copy number 3: 18,583; copy number 4: 11,737; copy number 5: 6,962; copy number 6: 4,518; copy number 7: 2,285; copy number 8: 681; copy number 9: 37; copy number 10: 156; copy number 13: 32; copy number 15: 33; copy number 18: 27; copy number 19: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-13-1410-01): tumor purity 0.81, ploidy 3.65, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,269 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,149,582–154,155,116, 68 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr2:74,532,258–74,893,359, 11 genes, copy number 9 (within-gene range 5–9): LOXL3, DOK1, M1AP, TOR1BP1, TVP23BP2, SEMA4F, AC007387.2, RPS28P5, AC007387.1, AC019069.1, HK2.
- chr2:74,919,555–74,924,846, 1 gene, copy number 9: AC104135.1.
- chr3:107,834,586–109,151,401, 22 genes, copy number 7 (within-gene range 4–7): LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2, DZIP3, AC092185.1, RETNLB, TRAT1, GUCA1C, MORC1, U3, MORC1-AS1, C3orf85.
- chr3:166,293,756–198,222,513, 623 genes, copy number 7–8 (broad region; genes not listed).
- chr4:69,408,828–71,572,087, 46 genes, copy number 13–18 (within-gene range 4–18): UGT2B24P, AC108078.3, AC108078.2, UGT2B4, UGT2A3P7, AC093829.1, UGT2A2, UGT2A1, SULT1B1, SULT1D1P, AC108941.3, SULT1E1, AC108941.1, CSN1S1, CSN2, STATH, HTN3, HTN1, CSN1S2AP, PRR27, ODAM, FDCSP, CSN3, CABS1, SMR3A, SMR3B, OPRPN, MUC7, AMTN, AMBN, ENAM, AC009570.2, JCHAIN, UTP3, RNU6-520P, RNU6-784P, AC009570.1, RUFY3, GRSF1, U6, RNU6-891P, MOB1B, DCK, SLC4A4, AC096713.1, LDHAL6EP.
- chr6:13,924,446–14,006,901, 3 genes, copy number 7: RNF182, MRPL35P1, AL022396.1.
- chr6:36,493,892–36,986,298, 20 genes, copy number 7 (within-gene range 5–7): STK38, RN7SL748P, SRSF3, MIR3925, RNU1-88P, Y_RNA, PANDAR, LAP3P2, CDKN1A, DINOL, RAB44, Z85996.1, CPNE5, Z85996.2, Z85996.3, PPIL1, C6orf89, AL122034.1, PI16, MTCH1.
- chr6:37,819,727–38,154,624, 1 gene, copy number 8 (within-gene range 5–8): ZFAND3.
- chr6:38,002,832–44,553,281, 188 genes, copy number 8–15 (broad region; genes not listed).
- chr9:32,293,558–32,454,769, 3 genes, copy number 10: RNA5SP281, SLC25A5P8, ACO1.
- chr10:117,425,194–119,459,745, 34 genes, copy number 7–13: AC005871.2, EMX2OS, EMX2, AC005871.1, AL356419.1, LINC02674, AL513324.1, RAB11FIP2, AC022395.1, CASC2, AL354863.1, FAM204A, LINC00867, SLC25A18P1, PRLHR, TOMM22P5, CACUL1, AL139407.1, AL157388.1, RPL17P36, LDHAP5, NANOS1, EIF3A, SNORA19, AL355598.1, AL355598.2, DENND10, SFXN4, PRDX3, GRK5, GRK5-IT1, RN7SL749P, AL583824.1, MIR4681.
- chr10:124,397,303–124,988,189, 17 genes, copy number 19: OAT, NKX1-2, AL445237.1, LHPP, RPS10P18, AC068896.1, FAM53B, AL513190.1, FAM53B-AS1, EEF1AKMT2, Y_RNA, ABRAXAS2, Y_RNA, NPM1P31, AL731577.2, ZRANB1, AL731577.1.
- chr10:124,996,064–125,001,491, 1 gene, copy number 19: AL731571.1.
- chr10:128,912,810–129,973,053, 15 genes, copy number 7 (within-gene range 5–7): LINC02667, AL355537.1, AL355537.2, AL391869.1, AL359508.1, MGMT, AL355531.1, AL157832.2, AL157832.1, LINC02666, EBF3, AL354950.2, MIR4297, AL354950.1, AL354950.3.
- chr12:71,439,798–73,846,188, 29 genes, copy number 7: LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8.
- chr12:73,906,940–73,919,337, 1 gene, copy number 7: AC136188.1.
- chr19:6,952,500–6,997,872, 1 gene, copy number 8 (within-gene range 5–8): ADGRE4P.
- chr19:7,005,012–15,836,328, 496 genes, copy number 8 (broad region; genes not listed).
- chr19:17,747,718–22,261,335, 223 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr19:22,298,977–22,299,868, 1 gene, copy number 7: BNIP3P31.
- chr19:30,850,975–39,391,154, 354 genes, copy number 7–9 (broad region; genes not listed).
- chr19:40,023,384–43,781,257, 192 genes, copy number 7 (broad region; genes not listed).
- chr19:43,794,309–43,795,658, 1 gene, copy number 7: AC115522.1.
- chr20:28,563,850–64,313,132, 918 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 176. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
